TCGA case TCGA-EE-A3JD — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b8a1732f-c1cb-4a02-af4f-61b63d3d52df

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 70 years; Vital status: Dead; Days to death: 832 days (2.3 years).

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 71.0 years (25,930 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: TX; AJCC pathologic N: N2b; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, prior to procurement.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Classification of tumor: Prior primary; Age at diagnosis: 63.3 years (23,128 days); Days to diagnosis: -2,802 days (-7.7 years).
3. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 72.0 years (26,294 days); Days to diagnosis: 364 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Bowel.
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 72.1 years (26,328 days); Days to diagnosis: 398 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 364 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 364 days.
- Day 398 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 398 days (1.1 years).
- Days to follow up: 832 days (2.3 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A3JD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A3JD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-EE-A3JD-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A3JD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Large bowel.
- Other malignancy form, Surgery: Other malignancy surgery type: bowel resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 832 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 832 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 364 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A3JD-06A-11D-A20B-01): tumor purity 0.18, ploidy 2.04, whole-genome doublings 0.
